CCDI case PBCTRA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/a9812c6e-e323-4634-adc6-c73a145358c6

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Other ill-defined sites; Age at diagnosis: 4.9 years (1,787 days).

Biospecimens (3 samples)
- Sample 0DZ4M2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DZ4MD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DZ4NY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
